Somatic mutation profile of tumor specimen TCGA-KB-A6F7-01A (aliquot TCGA-KB-A6F7-01A-12D-A32N-08) from TCGA case TCGA-KB-A6F7, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 54.1 years (19,765 days).
Specimen TCGA-KB-A6F7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5914f82-1ffd-43c1-bd17-ebfbed0bbf67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KB-A6F7-10A (Blood Derived Normal), aliquot TCGA-KB-A6F7-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cefa17af-4524-4a72-ac27-4297d18f6c6f

The open-access MAF lists 116 somatic variants for this specimen: 91 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 24, Nonsense Mutation 8, Frame Shift Del 5, Frame Shift Ins 2, Splice Site 2, 5'Flank 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 40/114 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61689314, COSV61696148; called by muse, mutect2, varscan2
- ABCB1 | c.95C>A p.P32Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.404); catalogued as COSV99713162; called by muse, mutect2
- AFF2 | c.2869A>C p.T957P | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV99664310; called by muse, mutect2, varscan2
- AGAP3 | c.1479C>A p.H493Q (on ENST00000622464; = p.H529Q on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.049); catalogued as COSV101257202; called by muse, mutect2, varscan2
- AGMAT | c.190G>T p.V64L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV101011787; called by muse, mutect2, varscan2
- ARAF | c.1440G>T p.M480I | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99283222; called by muse, mutect2
- ARAF | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | catalogued as COSV99283257; called by muse, mutect2
- ARID1A | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 101/226 reads (45%) | catalogued as COSV61376670; called by muse, mutect2, varscan2
- ARMC4 | c.913T>G p.F305V | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53464015, COSV53466754; called by muse, mutect2, varscan2
- BPIFB2 | c.867C>A p.D289E | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.185); catalogued as COSV99401427; called by muse, mutect2, varscan2
- C2orf78 | c.1941A>C p.K647N | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as COSV101280977; called by muse, mutect2, varscan2
- CDYL | c.71C>A p.P24Q | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100189437; called by muse, mutect2
- CDYL | c.1579G>A p.G527R (on ENST00000328908 / NM_001368125.1; = p.G473R on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.423); catalogued as rs771808805, COSV100189438; called by muse, mutect2, varscan2
- CHRM3 | c.920A>C p.K307T | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.061); catalogued as COSV99698516; called by muse, mutect2, varscan2
- CSGALNACT1 | c.429T>A p.Y143* | Nonsense Mutation (SNP) | VAF 19/148 reads (13%) | catalogued as COSV100175053; called by muse, mutect2, varscan2
- CTH | c.999+1G>T p.X333_splice | Splice Site (SNP) | VAF 16/65 reads (25%) | catalogued as COSV100697092; called by muse, mutect2, varscan2
- CYP11B1 | c.168G>C p.W56C | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1383321200, CM156820, COSV99455177; called by muse, mutect2, varscan2
- DZIP1L | c.2212G>C p.E738Q | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100551398; called by muse, mutect2, varscan2
- ELAPOR2 | c.2701T>A p.W901R (on ENST00000450689 / NM_001142749.3; = p.W734R on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51885728, COSV99788853; called by muse, mutect2, varscan2
- ETNPPL | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs766768915, COSV56595443; called by muse, mutect2, varscan2
- EZH1 | c.737A>G p.E246G | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as COSV101331376; called by muse, mutect2
- FAM111B | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as COSV100639297; called by muse, mutect2
- FLNB | c.3995A>T p.Q1332L | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV99913406; called by muse, mutect2
- GAPDH | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); catalogued as COSV99975560; called by muse, mutect2, varscan2
- GRIN3A | c.368G>A p.W123* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100701534; called by muse, mutect2
- GRIPAP1 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1557062819, COSV100904298; called by muse, mutect2
- HBEGF | c.77T>G p.L26R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV99138241; called by muse, mutect2, varscan2
- HK3 | c.1642T>C p.F548L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99458599; called by muse, mutect2
- HPR | c.637A>G p.N213D | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375115348; called by muse, mutect2, varscan2
- IMMP2L | c.469C>A p.Q157K | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV59241624; called by muse, mutect2
- KCNH5 | c.2612G>A p.S871N | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.584); catalogued as COSV100526725; called by muse, varscan2
- KIFAP3 | c.1509T>A p.D503E | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV100846946, COSV63031170; called by muse, mutect2, varscan2
- KLHL41 | c.1233G>T p.E411D | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99500393; called by muse, mutect2
- KRT79 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs149430221; called by muse, mutect2, varscan2
- LIMK1 | c.1569C>T p.G523= | Splice Region (SNP) | VAF 12/173 reads (7%) | catalogued as COSV100283213; called by muse, mutect2
- MAEL | c.908+1G>A p.X303_splice | Splice Site (SNP) | VAF 15/140 reads (11%) | catalogued as rs757249676, COSV63305723; called by muse, mutect2, varscan2
- MAN2A2 | c.3052T>A p.Y1018N | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV100847877; called by muse, mutect2
- MARCO | c.1295G>T p.R432L | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100503536, COSV59053740; called by muse, mutect2, varscan2
- MED13 | c.5012T>C p.L1671P | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV101181112; called by muse, mutect2, varscan2
- MTIF2 | c.1903A>C p.T635P | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV99703186; called by muse, mutect2, varscan2
- MTMR6 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV101110782; called by muse, mutect2, varscan2
- MUC16 | c.38995T>C p.S12999P | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.044); catalogued as COSV67474163; called by muse, mutect2, varscan2
- MVP | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as rs148167046, COSV62422332; called by muse, mutect2, varscan2
- NCK1 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 11/110 reads (10%) | catalogued as COSV56637012, COSV99999376; called by muse, mutect2, varscan2
- NEFH | c.1336G>T p.V446L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100151600, COSV60218077; called by muse, mutect2, varscan2
- NIPBL | c.4694T>A p.F1565Y | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99240779; called by muse, mutect2, varscan2
- NMRAL1 | c.803C>G p.P268R | Missense Mutation (SNP) | VAF 16/335 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99361793; called by muse, mutect2
- NPAP1 | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.763); catalogued as rs772619381, COSV61512304; called by muse, mutect2, varscan2
- NUP210L | c.4574del p.T1525Mfs*3 | Frame Shift Del (DEL) | VAF 14/119 reads (12%) | catalogued as COSV55153197; called by mutect2, pindel, varscan2
- ODAPH | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs754029402, COSV100290190; called by muse, mutect2, varscan2
- OR10G4 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs201358968; called by muse, mutect2, varscan2
- OR5M3 | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as COSV100392529; called by muse, mutect2
- PDC | c.293T>C p.M98T | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1006123938, COSV100414821; called by muse, mutect2
- PDE6A | c.2242C>A p.L748M | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs963290822, COSV99678321; called by muse, mutect2, varscan2
- PFAS | c.3598G>T p.G1200W | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100118958; called by muse, mutect2, varscan2
- PLAG1 | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 83/289 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); catalogued as rs1275825136, COSV100387933; called by muse, mutect2, varscan2
- PPIG | c.790C>G p.L264V | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99644586; called by muse, mutect2, varscan2
- PPM1L | c.943C>G p.R315G | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.236); catalogued as COSV55560921, COSV99861825; called by muse, mutect2
- PRKCQ | c.1843G>A p.V615M | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); catalogued as rs775800081, COSV54116126; called by muse, mutect2, varscan2
- PSRC1 | c.825T>A p.S275R (on ENST00000409138 / NM_001363309.1; = p.S245R on NM_032636.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as COSV100883518; called by muse, mutect2, varscan2
- SAMD9 | c.4539G>C p.Q1513H | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV101180271; called by muse, mutect2, varscan2
- SLC44A4 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs779511700, COSV57669199; called by muse, mutect2
- SLITRK1 | c.843del p.F281Lfs*45 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | catalogued as COSV65675146; called by mutect2, pindel, varscan2
- SNAI2 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99194961; called by muse, mutect2
- SOX8 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV99559249; called by muse, mutect2, varscan2
- SPACA7 | c.33C>A p.C11* | Nonsense Mutation (SNP) | VAF 3/41 reads (7%) | catalogued as COSV99366660; called by muse, mutect2
- SPARC | c.231C>A p.C77* | Nonsense Mutation (SNP) | VAF 24/166 reads (14%) | catalogued as COSV99163805; called by muse, mutect2, varscan2
- SPAST | c.1637G>C p.G546A | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as COSV100188569; called by muse, mutect2
- SRC | c.1538A>G p.E513G | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV100658092, COSV62439431; called by muse, mutect2
- SYNE2 | c.12007G>A p.E4003K | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV100647782; called by muse, mutect2, varscan2
- TCF25 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776257664, COSV99642961; called by muse, mutect2, varscan2
- TIGD7 | c.113G>C p.S38T | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV99239891; called by muse, mutect2, varscan2
- UBE4B | c.1990G>A p.V664I (on ENST00000343090 / NM_001105562.3; = p.V535I on NM_006048.5) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.084); catalogued as rs950908669, COSV99476743; called by muse, mutect2, varscan2
- USH2A | c.959T>A p.I320N | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100235773; called by muse, mutect2, varscan2
- VASN | c.1435G>T p.G479W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV99227706; called by muse, mutect2, varscan2
- WDR48 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56532723; called by muse, mutect2, varscan2
- WLS | c.1261C>G p.R421G | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52047086, COSV99259753; called by muse, mutect2, varscan2
- ZFP3 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 38/121 reads (31%) | catalogued as COSV100603812; called by muse, mutect2, varscan2
- ZFP57 | c.1255A>C p.K419Q | Missense Mutation (SNP) | VAF 34/347 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.698); catalogued as COSV100971880; called by muse, mutect2
- ZNF212 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs1285847181, COSV100242373; called by muse, mutect2, varscan2
- ZNF365 | c.27C>A p.S9R | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.295); catalogued as COSV101237964; called by muse, mutect2
- ZNF592 | c.1633A>G p.K545E | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100245896; called by muse, mutect2
- ZNF667 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99410501; called by muse, mutect2, varscan2
- ZSCAN29 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV99539097; called by muse, mutect2, varscan2
- ABCB8 | c.159_183del p.Y54Pfs*18 (on ENST00000297504 / NM_001282291.2; = p.Y37Pfs*18 on NM_007188.5) | Frame Shift Del (DEL) | VAF 28/174 reads (16%) | called by mutect2, pindel
- BMPR1A | c.424_428dup p.I143Mfs*3 | Frame Shift Ins (INS) | VAF 19/81 reads (23%) | called by mutect2, pindel, varscan2
- GSPT1 | c.1236_1243del p.V413Yfs*6 (on ENST00000420576 / NM_001130007.2; = p.V551Yfs*6 on NM_002094.4) | Frame Shift Del (DEL) | VAF 21/234 reads (9%) | called by mutect2, pindel
- PLK1 | c.1572_1592del p.H524_V530del | In Frame Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel
- SESN3 | c.888_889del p.L298Ffs*17 | Frame Shift Del (DEL) | VAF 11/86 reads (13%) | called by mutect2, pindel, varscan2
- TMEM51 | c.214dup p.A72Gfs*17 | Frame Shift Ins (INS) | VAF 20/150 reads (13%) | called by mutect2, pindel, varscan2
- ZNF567 | c.191C>A p.P64Q (on ENST00000536254 / NM_001322913.1; = p.P33Q on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2
- AGBL1 | c.1257G>T p.V419= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV101223251; called by muse, mutect2, varscan2
- ATM | c.6732A>G p.R2244= | Silent (SNP) | VAF 7/104 reads (7%) | catalogued as COSV99589820; called by muse, mutect2
- CD93 | c.513C>T p.P171= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as rs759482480, COSV55664474; called by muse, mutect2, varscan2
- CHD9 | c.618T>C p.H206= | Silent (SNP) | VAF 74/207 reads (36%) | catalogued as rs754207747, COSV101272143; called by muse, mutect2, varscan2
- CNTN6 | c.642A>G p.L214= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100610802; called by muse, mutect2, varscan2
- CSMD1 | c.6450C>T p.N2150= (on ENST00000520002; = p.N2149= on NM_033225.6) | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs753995950, COSV100148623, COSV100153116; called by muse, mutect2, varscan2
- CTAGE1 | c.1950C>T p.P650= | Silent (SNP) | VAF 132/680 reads (19%) | catalogued as rs748734100, COSV66943375; called by muse, mutect2, varscan2
- DNAH17 | c.10329C>T p.D3443= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs573075069, COSV67759257; called by mutect2, varscan2
- DUOXA2 | c.501C>T p.C167= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as rs781126484, COSV99973241; called by muse, mutect2, varscan2
- EBF3 | c.966C>T p.G322= (on ENST00000355311 / NM_001375392.1; = p.G313= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as rs151206880; called by muse, mutect2, varscan2
- ELAPOR2 | c.2700G>T p.V900= (on ENST00000450689 / NM_001142749.3; = p.V733= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 57/206 reads (28%) | catalogued as COSV99788858; called by muse, mutect2, varscan2
- GAS2 | c.594A>G p.T198= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV99535147; called by muse, mutect2
- HIPK3 | c.1422A>T p.V474= | Silent (SNP) | VAF 6/119 reads (5%) | catalogued as COSV100305812; called by muse, mutect2
- IL20RB | c.804G>A p.V268= | Silent (SNP) | VAF 53/565 reads (9%) | catalogued as COSV100291084; called by muse, mutect2
- INTS14 | c.1533T>G p.S511= (on ENST00000313182 / NM_001366360.2; = p.S432= on NM_001136043.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/191 reads (10%) | catalogued as COSV99971098; called by muse, mutect2, varscan2
- KIRREL3 | c.2031C>T p.N677= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV101375196; called by muse, mutect2
- LINGO2 | c.1617A>G p.K539= | Silent (SNP) | VAF 15/142 reads (11%) | catalogued as COSV100430614; called by muse, mutect2, varscan2
- NEB | c.11404A>C p.R3802= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV99423760; called by muse, mutect2, varscan2
- PIWIL1 | c.2562G>T p.L854= | Silent (SNP) | VAF 15/200 reads (8%) | catalogued as COSV99806458; called by muse, mutect2
- PTPDC1 | c.522G>T p.V174= (on ENST00000375360 / NM_177995.3; = p.V226= on NM_152422.4) | Silent (SNP) | VAF 28/233 reads (12%) | catalogued as COSV99997649; called by muse, mutect2, varscan2
- RAPGEF4 | c.2616C>T p.N872= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs759396088, COSV51393616; called by muse, mutect2, varscan2
- SLC6A11 | c.1098C>A p.P366= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99594559; called by mutect2, varscan2
- SYNE1 | c.19917T>C p.S6639= (on ENST00000367255 / NM_182961.4; = p.S6568= on NM_033071.3) | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV99566212; called by muse, mutect2, varscan2
- SYNE4 | c.327G>T p.L109= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99431093; called by muse, mutect2
- ZBTB37 | chr1:173864197 T>A | 5'Flank (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
